CPTAC case C3N-01168 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/81d68662-e30b-48fd-b659-e991a3119445

Demographics
Sex at birth: female; Race: white; Year of birth: 1956; Vital status: Dead; Days to death: 415 days (1.1 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 60.7 years (22,172 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 415 days (1.1 years); Progression or recurrence: yes; Days to recurrence: 320 days; Days to last follow up: 415 days (1.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 10; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 397 days (1.1 years); Disease response: Progressive Disease; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 415 days (1.1 years); Disease response: Progressive Disease; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 461 days (1.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 320 days; Karnofsky performance status: 70; ECOG performance status: 2.

Other clinical attributes
- Weight: 51 kg; Height: 158 cm; BMI: 20.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01168-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 215 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01168-22: Section location: Head; Percent tumor nuclei: 40; Percent necrosis: 2.
- Sample C3N-01168-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 150 mg.
- Sample C3N-01168-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
